Gene-level copy-number profile of tumor specimen TCGA-D8-A1JK-01A from TCGA case TCGA-D8-A1JK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-D8-A1JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.7013da0d-5e90-4f8d-a489-8077b55309b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/adc91e8c-7e38-4ba6-8e1b-55352a6e189f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 99; copy number 1: 859; copy number 2: 2,216; copy number 3: 17,105; copy number 4: 16,526; copy number 5: 12,409; copy number 6: 6,804; copy number 7: 2,542; copy number 8: 245; copy number 9: 712; copy number 10: 54; copy number 11: 47; copy number 12: 29; copy number 13: 13; copy number 15: 73; copy number 16: 84.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JK-01A-11D-A13J-01): tumor purity 0.41, ploidy 4.2, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,140,214–27,610,745, 99 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,012 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,038,529–85,578,363, 36 genes, copy number 9 (within-gene range 4–9): AC104454.2, AL359504.1, PRKACB, TXN2P1, NEDD8P1, AL359273.1, SAMD13, AL359273.2, UOX, DNASE2B, AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS, AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1, LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1.
- chr1:221,701,424–221,978,523, 4 genes, copy number 9 (within-gene range 6–9): DUSP10, LINC01655, RNU6-403P, LINC02257.
- chr3:70,959,226–71,827,471, 12 genes, copy number 15 (within-gene range 3–15): AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P.
- chr3:72,301,616–72,740,525, 8 genes, copy number 12: AC134508.2, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4.
- chr3:72,772,539–72,773,471, 1 gene, copy number 12: AC134050.1.
- chr5:19,471,296–21,032,845, 8 genes, copy number 10 (within-gene range 7–10): CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1.
- chr6:86,170,447–87,155,285, 16 genes, copy number 11: RAB1AP2, NDUFA5P9, AL391417.1, RN7SL643P, AL353133.1, AL353133.2, AL157777.1, AL157777.2, HTR1E, RPL7P29, MTHFD2P2, AL138827.1, RN7SKP209, CGA, RCN1P1, AL139274.2.
- chr6:113,791,829–114,471,705, 11 genes, copy number 9 (within-gene range 4–9): FO393415.2, FO393415.1, MARCKS, MROCKI, LINC02880, HDAC2, HDAC2-AS2, NUDT19P3, HS3ST5, RPSAP43, RNA5SP213.
- chr7:44,601,032–45,768,985, 29 genes, copy number 9 (within-gene range 6–9): AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2, NACAD, TBRG4, SNORA5A, SNORA5C, SNORA5B, RAMP3, AC073968.2, AC073968.1, ELK1P1, AC073325.1, AC073325.2, ADCY1, SEPTIN7P2.
- chr7:157,138,916–157,417,439, 6 genes, copy number 9: UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6.
- chr8:38,699,274–41,440,419, 43 genes, copy number 10–16: AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1.
- chr8:46,028,804–50,796,692, 74 genes, copy number 13–15 (within-gene range 8–15) (broad region; genes not listed).
- chr8:57,994,509–58,204,279, 1 gene, copy number 10 (within-gene range 5–10): FAM110B.
- chr8:58,091,442–58,272,450, 5 genes, copy number 10: AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2.
- chr8:59,455,885–60,967,775, 23 genes, copy number 9: RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2.
- chr8:112,222,928–114,318,911, 11 genes, copy number 10 (within-gene range 5–10): CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1.
- chr10:91,765,899–91,909,486, 7 genes, copy number 11: FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1.
- chr13:93,226,612–94,408,020, 7 genes, copy number 9 (within-gene range 3–9): AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35, GPC6-AS1.
- chr14:29,210,986–37,567,095, 152 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr14:94,304,248–94,675,829, 16 genes, copy number 11 (within-gene range 8–11): SERPINA6, SERPINA2, SERPINA1, AL132708.1, SERPINA11, SERPINA9, SERPINA12, AL132990.1, SERPINA4, SERPINA5, AL049839.2, AL049839.3, SERPINA3, ADIPOR1P2, SERPINA13P, AL049839.1.
- chr15:26,971,181–27,541,984, 1 gene, copy number 9 (within-gene range 4–9): GABRG3.
- chr15:27,280,318–27,541,991, 6 genes, copy number 9: RNA5SP391, SERPINE4P, AC144833.1, AC104002.1, AC104002.2, AC104002.3.
- chr16:28,258,686–31,074,240, 225 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:51,386,957–64,313,132, 310 genes, copy number 9–16 (within-gene range 5–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 859. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
